Somatic mutation profile of tumor specimen TCGA-FI-A2F4-01A (aliquot TCGA-FI-A2F4-01A-11D-A17D-09) from TCGA case TCGA-FI-A2F4, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IC; Tumor grade: G3; Age at diagnosis: 64.7 years (23,621 days).
Specimen TCGA-FI-A2F4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9703ae78-c0b2-46ea-8822-04555b7a95a6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FI-A2F4-10B (Blood Derived Normal), aliquot TCGA-FI-A2F4-10B-01D-A17D-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49608101-19d9-45dd-8e46-52bd9f8edfd0

The open-access MAF lists 2,361 somatic variants for this specimen: 1,805 protein-altering or splice-affecting, 500 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,352, Silent 500, Frame Shift Del 146, Frame Shift Ins 124, Splice Site 81, Nonsense Mutation 63, Intron 31, Splice Region 30, RNA 7, 3'UTR 5, 5'UTR 5, 5'Flank 4.

Variants (750 of 2,361; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMT | c.59del p.P20Rfs*76 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | catalogued as rs386833686, CD983450, COSV56469502; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.657T>G p.F219L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV57247054, COSV57254375; called by muse, mutect2, varscan2
- IBA57 | c.678A>G p.Q226= | Splice Region (SNP) | VAF 21/103 reads (20%) | catalogued as rs876657407, CS151467, COSV100812772; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMC3 | c.3181del p.D1061Tfs*20 | Frame Shift Del (DEL) | VAF 25/62 reads (40%) | catalogued as rs1554789671; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LDLR | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs879254544, CM055382, COSV99369893; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- LRP2 | c.13139dup p.C4381Mfs*12 | Frame Shift Ins (INS) | VAF 12/29 reads (41%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MPZ | c.411C>T p.G137= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs1558153994, CS113136, COSV100337877; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NKX2-1 | c.254dup p.Y86Lfs*323 | Frame Shift Ins (INS) | VAF 11/35 reads (31%) | catalogued as rs587776709; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3R2 | c.1690A>G p.K564E | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs886041602, COSV55847404; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.92del p.N31Tfs*23 | Frame Shift Del (DEL) | VAF 21/69 reads (30%) | catalogued as rs1564814427; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- RYR2 | c.527G>A p.R176Q | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs794728708, CM010421, COSV63694898; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SERPINC1 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 32/143 reads (22%) | catalogued as rs121909562, CM910056, COSV100875048; ClinVar: pathogenic; called by muse, mutect2, varscan2
- WRN | c.3382del p.S1128Vfs*34 | Frame Shift Del (DEL) | VAF 12/129 reads (9%) | catalogued as rs778872619; ClinVar: pathogenic; called by mutect2, pindel
- A1CF | c.770-1G>T p.X257_splice | Splice Site (SNP) | VAF 13/29 reads (45%) | catalogued as COSV50957972, COSV99256082; called by muse, mutect2, varscan2
- AAMDC | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100489948; called by muse, mutect2, varscan2
- AASS | c.310A>G p.K104E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100741775; called by muse, mutect2, varscan2
- ABCA12 | c.5746A>T p.T1916S (on ENST00000272895 / NM_173076.3; = p.T1598S on NM_015657.3) | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.634); catalogued as COSV99789807; called by muse, mutect2, varscan2
- ABCA13 | c.894G>T p.K298N | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.49); catalogued as COSV101330030, COSV70040184; called by muse, mutect2
- ABCA13 | c.6671C>A p.A2224D | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.53); catalogued as COSV101330031; called by muse, mutect2, varscan2
- ABCA13 | c.13268dup p.T4424Yfs*84 | Frame Shift Ins (INS) | VAF 35/110 reads (32%) | catalogued as rs1250505666; called by mutect2, pindel, varscan2
- ABCB6 | c.2370T>A p.N790K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV99202415; called by muse, mutect2
- ABCB6 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); catalogued as rs775873530, COSV99202416; called by muse, mutect2, varscan2
- ABCC11 | c.3007C>A p.L1003I | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.782); catalogued as COSV100750745; called by muse, mutect2, varscan2
- ABCD1 | c.944C>A p.S315* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | catalogued as CM011735, COSV104373635, COSV99497536; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.832A>G p.K278E | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99865386; called by muse, mutect2
- ABL1 | c.289G>T p.G97W | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100583944; called by muse, mutect2, varscan2
- ABLIM1 | c.344C>T p.T115I | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV99521964; called by muse, mutect2, varscan2
- ABR | c.2526del p.I843Ffs*41 (on ENST00000302538 / NM_021962.5; = p.I806Ffs*41 on NM_001092.5) | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | catalogued as rs750897785; called by mutect2, pindel, varscan2
- AC006059.2 | c.824T>C p.V275A | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV100045524; called by muse, varscan2
- AC006059.2 | c.188T>C p.L63P | Missense Mutation (SNP) | VAF 44/134 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.02); catalogued as COSV100045527; called by muse, mutect2, varscan2
- AC008397.2 | c.1514T>C p.M505T | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99441650; called by muse, mutect2, varscan2
- AC244197.3 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.869); catalogued as COSV100557978; called by muse, mutect2, varscan2
- ACACB | c.938T>C p.M313T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.262); catalogued as COSV100622838; called by muse, mutect2, varscan2
- ACADSB | c.734A>G p.H245R | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV100715184; called by muse, mutect2, varscan2
- ACER2 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.882); catalogued as COSV100575804; called by muse, mutect2, varscan2
- ACOT6 | c.340A>G p.S114G | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV101141937; called by muse, mutect2
- ACOT9 | c.1172T>C p.F391S | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100321266; called by muse, mutect2
- ACSM1 | c.752+1G>A p.X251_splice | Splice Site (SNP) | VAF 26/68 reads (38%) | catalogued as COSV99532923; called by muse, varscan2
- ACSS1 | c.1415C>A p.P472H | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100053694; called by muse, mutect2, varscan2
- ACTL7B | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.492); catalogued as rs1378751423, COSV101012522; called by muse, mutect2, varscan2
- ACTR5 | c.1433+2T>C p.X478_splice | Splice Site (SNP) | VAF 23/67 reads (34%) | catalogued as rs371139957; called by muse, mutect2, varscan2
- ACVRL1 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs769850351, COSV101187905; called by muse, mutect2, varscan2
- ADAMTS16 | c.3412-1G>A p.X1138_splice | Splice Site (SNP) | VAF 9/22 reads (41%) | catalogued as COSV99941077; called by muse, mutect2, varscan2
- ADAMTS17 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.575); catalogued as COSV99170646; called by muse, mutect2, varscan2
- ADAMTSL3 | c.5068G>T p.E1690* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV99718665; called by muse, mutect2, varscan2
- ADAMTSL4 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99647259; called by muse, mutect2, varscan2
- ADCY5 | c.1127T>G p.L376R | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV101518430; called by muse, mutect2, varscan2
- ADD3 | c.1460A>T p.D487V | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.97); catalogued as COSV99523385; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRD1 | c.2309G>A p.G770D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444768149, COSV99895304; called by muse, mutect2, varscan2
- ADGRV1 | c.10205T>C p.L3402P | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101315875, COSV67982227; called by muse, mutect2, varscan2
- ADIPOR2 | c.800A>G p.D267G | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV100840091; called by muse, mutect2, varscan2
- ADNP2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs780534183, COSV51540836; called by muse, mutect2, varscan2
- ADRB1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.624); catalogued as COSV100992280; called by muse, mutect2, varscan2
- AGAP2 | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.505); catalogued as COSV99223093; called by muse, mutect2, varscan2
- AGL | c.886C>T p.L296F | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.07); catalogued as COSV54052591; called by muse, mutect2, varscan2
- AHCTF1 | c.6505dup p.I2169Nfs*35 (on ENST00000366508; = p.I2143Nfs*35 on NM_015446.5) | Frame Shift Ins (INS) | VAF 18/84 reads (21%) | catalogued as rs1251286748; called by mutect2, varscan2
- AHCTF1 | c.1933T>C p.C645R (on ENST00000366508; = p.C619R on NM_015446.5) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.962); catalogued as COSV100403637; called by muse, mutect2, varscan2
- AHNAK2 | c.4349C>A p.P1450H | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.065); catalogued as rs1273440213, COSV100317431; called by muse, mutect2, varscan2
- AHSA1 | c.411G>T p.K137N | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV99375958; called by muse, mutect2, varscan2
- AKAP13 | c.5309A>T p.D1770V (on ENST00000394518 / NM_007200.5; = p.D1774V on NM_006738.6) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as rs1347849052, COSV100773739; called by muse, mutect2, varscan2
- AKAP6 | c.4522T>C p.S1508P | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV99800605; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 18/46 reads (39%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1A1 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100698720; called by muse, mutect2, varscan2
- AKR1C4 | c.882A>C p.K294N | Missense Mutation (SNP) | VAF 44/110 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV99578683; called by muse, mutect2, varscan2
- AKT2 | c.784G>A p.A262T | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100251605; called by muse, mutect2, varscan2
- ALDH1A3 | c.1230G>T p.E410D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.153); catalogued as COSV100320195; called by muse, mutect2, varscan2
- ALDH3A1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.525); catalogued as COSV99855864; called by muse, varscan2
- ALG1 | c.1013T>C p.F338S | Missense Mutation (SNP) | VAF 15/141 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV99275741; called by muse, mutect2
- ALG11 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as rs750430228, COSV101584285; called by muse, mutect2, varscan2
- ALMS1 | c.1735G>A p.G579R | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.08); PolyPhen benign (0.408); catalogued as COSV100042364; called by muse, mutect2, varscan2
- ALMS1 | c.8011C>T p.P2671S | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.747); catalogued as COSV100042365; called by muse, mutect2, varscan2
- ALPK3 | c.2106G>T p.K702N | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV99360842; called by muse, mutect2, varscan2
- ALS2 | c.4339C>T p.P1447S | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV99969260; called by muse, mutect2, varscan2
- AMHR2 | c.38C>T p.T13I | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV99143200; called by muse, mutect2, varscan2
- AMOTL1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.058); catalogued as COSV100504379; called by muse, mutect2, varscan2
- AMOTL1 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100504382; called by mutect2, varscan2
- AMPD3 | c.1957C>T p.H653Y (on ENST00000396553 / NM_001025389.2; = p.H662Y on NM_000480.3) | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.522); catalogued as rs1031653860, COSV101158163; called by muse, mutect2, varscan2
- ANK2 | c.3723A>C p.K1241N | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV100001487; called by muse, mutect2, varscan2
- ANK2 | c.11471C>T p.P3824L | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100001491; called by muse, mutect2, varscan2
- ANK3 | c.3191T>A p.I1064N (on ENST00000280772 / NM_001320874.2; = p.I198N on NM_001149.3) | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99779774; called by muse, mutect2, varscan2
- ANKAR | c.1970A>G p.Y657C | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as COSV99854207; called by muse, mutect2, varscan2
- ANKAR | c.3478T>C p.F1160L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV99854208; called by muse, mutect2, varscan2
- ANKDD1A | c.923G>A p.R308Q | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as rs758673713, COSV100731171; called by muse, mutect2, varscan2
- ANKIB1 | c.437dup p.N146Kfs*29 | Frame Shift Ins (INS) | VAF 24/75 reads (32%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKIB1 | c.1477C>T p.P493S | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs1337884668, COSV99728992; called by muse, mutect2, varscan2
- ANKRD35 | c.2405G>A p.G802E | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.925); catalogued as COSV100841724; called by muse, mutect2, varscan2
- ANKRD49 | c.584T>C p.L195P | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100119659; called by muse, mutect2, varscan2
- ANKS1A | c.2480C>T p.A827V | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100832400; called by muse, mutect2, varscan2
- ANKS1B | c.1176G>T p.E392D | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV100245405; called by muse, varscan2
- ANKS1B | c.1144A>G p.I382V | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV100245408; called by muse, varscan2
- ANO9 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as rs757068080, COSV100240724; called by muse, mutect2, varscan2
- ANPEP | c.710T>G p.L237R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100263022; called by muse, mutect2, varscan2
- ANXA11 | c.1201A>T p.M401L | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.011); catalogued as COSV99627115; called by muse, mutect2, varscan2
- AOC2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as rs753929672, COSV53824046; called by muse, mutect2, varscan2
- AP3B2 | c.1334A>G p.D445G | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99916458; called by muse, mutect2, varscan2
- APBB1 | c.849del p.G284Afs*48 | Frame Shift Del (DEL) | VAF 20/54 reads (37%) | catalogued as COSV54976931; called by pindel, varscan2
- APC | c.6656C>T p.A2219V | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs774479966, COSV99967709; called by muse, varscan2
- APC | c.8234C>T p.P2745L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs759421641, COSV99967711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- APEX1 | c.833T>A p.V278D | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99164477; called by muse, mutect2, varscan2
- APOB | c.12218A>G p.N4073S | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV99265518; called by muse, mutect2, varscan2
- APOB | c.9160G>T p.G3054W | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358164421, COSV51922437; called by muse, mutect2, varscan2
- APOL6 | c.970G>A p.V324M | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as rs753360497, COSV101290996; called by muse, mutect2, varscan2
- AQR | c.1954del p.T652Lfs*4 | Frame Shift Del (DEL) | VAF 37/108 reads (34%) | catalogued as COSV50029634; called by mutect2, pindel, varscan2
- AR | c.865G>A p.E289K | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.706); catalogued as rs750324117, CM035613, COSV65953437, COSV65963147; called by muse, mutect2, varscan2
- ARHGAP21 | c.2716A>G p.I906V | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.26); PolyPhen benign (0.138); catalogued as rs201415705, COSV100256180; called by muse, mutect2, varscan2
- ARHGAP30 | c.3049C>T p.R1017* (on ENST00000368013 / NM_001025598.2; = p.R806* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV100920252; called by muse, mutect2, varscan2
- ARHGAP32 | c.5899T>C p.Y1967H (on ENST00000310343 / NM_001378025.1; = p.Y1618H on NM_014715.4) | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV100087763; called by muse, mutect2, varscan2
- ARHGAP32 | c.4388A>G p.Q1463R (on ENST00000310343 / NM_001378025.1; = p.Q1114R on NM_014715.4) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated, low confidence (0.77); PolyPhen possibly damaging (0.852); catalogued as COSV100087768; called by muse, mutect2, varscan2
- ARHGAP32 | c.1310A>G p.Q437R (on ENST00000310343 / NM_001378025.1; = p.Q88R on NM_014715.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV100087769; called by muse, mutect2, varscan2
- ARHGDIB | c.388T>C p.Y130H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.198); catalogued as COSV99967346; called by muse, mutect2, varscan2
- ARHGEF10L | c.1237T>C p.Y413H | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99392795; called by muse, mutect2, varscan2
- ARHGEF11 | c.2489C>T p.A830V | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV59353384; called by muse, mutect2, varscan2
- ARHGEF11 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1267871600, COSV100810064; called by muse, mutect2, varscan2
- ARHGEF12 | c.914A>G p.D305G | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.925); catalogued as COSV100754891; called by muse, mutect2
- ARHGEF18 | c.1586A>G p.K529R (on ENST00000359920 / NM_001130955.2; = p.K425R on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.405); catalogued as rs1408979059, COSV100149490; called by mutect2, varscan2
- ARHGEF26 | c.47_48insA p.L17Ffs*63 | Frame Shift Ins (INS) | VAF 43/121 reads (36%) | catalogued as COSV100726545; called by mutect2, pindel, varscan2
- ARHGEF9 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as COSV99491748; called by muse, mutect2, varscan2
- ARID1B | c.4781C>T p.T1594I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.737); catalogued as CX1314077, COSV99268955; called by muse, mutect2, varscan2
- ARIH2 | c.901A>G p.N301D | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100711305; called by muse, mutect2, varscan2
- ARL4D | c.125A>G p.K42R | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.46); catalogued as COSV100186413; called by muse, mutect2, varscan2
- ARL6IP4 | c.713-1G>A p.X238_splice | Splice Site (SNP) | VAF 4/15 reads (27%) | catalogued as COSV99758853; called by muse, mutect2, varscan2
- ARMC8 | c.1681A>G p.T561A (on ENST00000469044 / NM_001363941.2; = p.T547A on NM_015396.6) | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.899); catalogued as rs765855433, COSV100509581; called by muse, mutect2, varscan2
- ARMCX3 | c.745T>C p.F249L | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.57); PolyPhen benign (0.078); catalogued as COSV100362256; called by muse, mutect2, varscan2
- ARMT1 | c.121A>G p.S41G | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100939788; called by muse, mutect2, varscan2
- ARR3 | c.829G>A p.A277T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99333653; called by muse, mutect2, varscan2
- ARRDC1 | c.1173del p.P392Qfs*8 | Frame Shift Del (DEL) | VAF 22/64 reads (34%) | catalogued as rs757365279, COSV58375691; called by mutect2, pindel, varscan2
- ARRDC3 | c.1100C>T p.A367V | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99475269; called by muse, mutect2, varscan2
- ARRDC4 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99164363; called by muse, mutect2, varscan2
- ART1 | c.499A>G p.S167G | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99167162; called by muse, mutect2, varscan2
- ART5 | c.789G>A p.G263= | Splice Region (SNP) | VAF 8/11 reads (73%) | catalogued as COSV100731632; called by muse, mutect2, varscan2
- ARVCF | c.2522A>G p.K841R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV99258618; called by muse, mutect2
- ASAP1 | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 21/82 reads (26%) | catalogued as COSV100727236; called by muse, mutect2, varscan2
- ASAP2 | c.849+2T>C p.X283_splice | Splice Site (SNP) | VAF 37/98 reads (38%) | catalogued as COSV55631129; called by muse, mutect2, varscan2
- ASB11 | c.68dup p.F24Lfs*2 | Frame Shift Ins (INS) | VAF 16/60 reads (27%) | catalogued as rs770804405; called by mutect2, varscan2
- ASCL4 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.294); catalogued as rs778208723, COSV60816844; called by muse, mutect2, varscan2
- ASH1L | c.4795A>G p.S1599G | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100853404; called by muse, mutect2, varscan2
- ASIC3 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1393352525, COSV52506636; called by muse, mutect2, varscan2
- ASL | c.790T>C p.C264R | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV100508880; called by muse, mutect2, varscan2
- ASMTL | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs200707318, COSV101187745; called by muse, mutect2, varscan2
- ASPM | c.6619A>C p.T2207P | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.756); catalogued as COSV99660323; called by muse, mutect2, varscan2
- ASTN1 | c.1918A>G p.S640G | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99921506; called by muse, mutect2, varscan2
- ATAD2 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.006); catalogued as COSV99784653; called by muse, mutect2, varscan2
- ATAD3A | c.817T>C p.S273P | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); catalogued as COSV100186320; called by muse, mutect2, varscan2
- ATF2 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.267); catalogued as COSV99908677; called by muse, mutect2, varscan2
- ATG16L2 | c.1001C>T p.A334V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100352246; called by muse, mutect2, varscan2
- ATG2A | c.4253G>T p.R1418L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372355626, COSV101034312; called by muse, mutect2, varscan2
- ATG4C | c.142T>C p.Y48H | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100508096; called by muse, mutect2, varscan2
- ATP10B | c.2915A>G p.K972R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.78); catalogued as COSV100514894; called by muse, mutect2
- ATP11A | c.265A>G p.T89A | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.298); catalogued as COSV99368388; called by muse, mutect2, varscan2
- ATP11C | c.2009G>A p.G670D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201635387, COSV100557867; called by muse, mutect2, varscan2
- ATP11C | c.71_72del p.T24Sfs*21 | Frame Shift Del (DEL) | VAF 12/47 reads (26%) | catalogued as rs1224866423; called by pindel, varscan2
- ATP13A1 | c.1286C>T p.T429I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV99366112; called by muse, mutect2, varscan2
- ATP1A4 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.124); catalogued as rs755062435, COSV100927535; called by muse, mutect2, varscan2
- ATP1A4 | c.1492-2A>G p.X498_splice | Splice Site (SNP) | VAF 12/71 reads (17%) | catalogued as COSV63627884; called by muse, mutect2, varscan2
- ATP2A3 | c.1508C>A p.P503H | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV99989117; called by muse, mutect2, varscan2
- ATP2B1 | c.3441T>A p.H1147Q | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.775); catalogued as COSV99665644; called by muse, mutect2, varscan2
- ATP2B2 | c.2269A>G p.N757D (on ENST00000352432; = p.N723D on NM_001683.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.95); PolyPhen benign (0.138); catalogued as COSV100659966; called by muse, mutect2, varscan2
- ATP2B4 | c.3417G>T p.E1139D | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.001); catalogued as COSV100397464; called by muse, mutect2, varscan2
- ATP6V1G3 | c.245A>G p.Q82R | Missense Mutation (SNP) | VAF 40/193 reads (21%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99810849; called by muse, mutect2, varscan2
- ATR | c.6222-1G>A p.X2074_splice | Splice Site (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100638199; called by muse, mutect2, varscan2
- ATR | c.4433T>C p.I1478T | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as COSV100638200; called by muse, mutect2, varscan2
- ATRX | c.5659T>C p.W1887R | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as COSV100970706; called by muse, mutect2, varscan2
- ATRX | c.2531C>T p.T844I | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.028); catalogued as COSV64876556; called by muse, mutect2, varscan2
- ATXN2 | c.3350G>A p.S1117N (on ENST00000550104; = p.S957N on NM_002973.4) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.107); catalogued as rs1325259789, COSV101112744; called by muse, mutect2, varscan2
- BACH2 | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.31); PolyPhen benign (0.078); catalogued as rs374812157, COSV57607740; called by muse, mutect2, varscan2
- BAG4 | c.378+1G>A p.X126_splice | Splice Site (SNP) | VAF 10/23 reads (43%) | catalogued as rs920087669, COSV99781839; called by muse, mutect2, varscan2
- BAG6 | c.344dup p.G116Wfs*11 | Frame Shift Ins (INS) | VAF 8/17 reads (47%) | catalogued as rs761315497; called by mutect2, varscan2
- BAHCC1 | c.7562C>T p.A2521V | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57027752; called by muse, mutect2, varscan2
- BAIAP2 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1311232269, COSV100348073; called by muse, mutect2, varscan2
- BARD1 | c.1788del p.K596Nfs*9 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV53612208; called by mutect2, pindel, varscan2
- BARD1 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as rs759732945, COSV99638639; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BATF | c.254T>A p.V85E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.95); catalogued as COSV54376806, COSV99708829; called by muse, mutect2, varscan2
- BCAS3 | c.1145T>C p.L382P | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as COSV101175874; called by muse, mutect2, varscan2
- BCAT2 | c.414T>C p.S138= | Splice Region (SNP) | VAF 26/86 reads (30%) | catalogued as COSV100302407, COSV60273619; called by muse, mutect2, varscan2
- BCL11B | c.493T>C p.S165P | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.91); catalogued as rs761975062, COSV100595505; called by muse, mutect2, varscan2
- BCO2 | c.1714T>C p.F572L | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.46); catalogued as COSV100730324; called by muse, mutect2, varscan2
- BCORL1 | c.4851C>T p.R1617= | Splice Region (SNP) | VAF 6/21 reads (29%) | catalogued as rs773549360, COSV99499351; called by muse, mutect2, varscan2
- BCORL1 | c.5042dup p.G1682Rfs*4 | Frame Shift Ins (INS) | VAF 14/38 reads (37%) | catalogued as rs768244116, COSV54407680; called by mutect2, varscan2
- BECN1 | c.938T>C p.L313P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.585); catalogued as COSV100162098; called by muse, mutect2, varscan2
- BEND2 | c.896A>G p.H299R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV101191994; called by muse, mutect2
- BEND6 | c.132T>A p.Y44* | Nonsense Mutation (SNP) | VAF 13/41 reads (32%) | catalogued as COSV100876836, COSV100876865; called by muse, mutect2, varscan2
- BEX5 | c.82T>C p.Y28H | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100375040; called by muse, mutect2
- BIN1 | c.1046C>A p.P349Q | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99387949; called by muse, mutect2, varscan2
- BIRC6 | c.12671C>T p.T4224I | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1443777667, COSV101428268; called by muse, mutect2, varscan2
- BNC1 | c.214A>G p.R72G | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV100597168; called by muse, mutect2, varscan2
- BNIP1 | c.376A>G p.T126A | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.039); catalogued as COSV99199395; called by muse, mutect2, varscan2
- BOC | c.2021G>A p.G674D | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99848654; called by muse, mutect2, varscan2
- BOD1L1 | c.926A>G p.Q309R | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99239292; called by muse, mutect2, varscan2
- BPNT1 | c.88A>G p.I30V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100435653; called by muse, mutect2, varscan2
- BRCA2 | c.7039C>A p.P2347T | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.428); catalogued as COSV101204200; called by muse, mutect2, varscan2
- BRD7 | c.1934A>G p.E645G | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV99575980; called by muse, mutect2, varscan2
- BRSK2 | c.1063dup p.R355Pfs*48 | Frame Shift Ins (INS) | VAF 15/54 reads (28%) | catalogued as rs779380593; called by mutect2, varscan2
- BSN | c.4996G>A p.V1666I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.782); catalogued as COSV99608357; called by muse, mutect2, varscan2
- BSN | c.8641-1G>T p.X2881_splice | Splice Site (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99608359; called by muse, mutect2, varscan2
- BTAF1 | c.4652C>A p.A1551D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.078); catalogued as COSV99795312; called by muse, mutect2, varscan2
- BTN2A2 | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as COSV100760385; called by muse, mutect2, varscan2
- BTN3A1 | c.1485T>A p.Y495* | Nonsense Mutation (SNP) | VAF 30/67 reads (45%) | catalogued as COSV99175794; called by muse, mutect2, varscan2
- BTNL9 | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.739); catalogued as COSV100576149; called by muse, mutect2, varscan2
- C11orf53 | c.463T>A p.F155I | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV99724735; called by muse, varscan2
- C15orf39 | c.121T>C p.C41R | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); catalogued as rs149365490; called by muse, mutect2, varscan2
- C15orf39 | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV100641334; called by muse, mutect2, varscan2
- C16orf78 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.2); catalogued as COSV100147717; called by muse, mutect2, varscan2
- C19orf18 | c.551G>A p.S184N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as COSV100071778; called by muse, mutect2, varscan2
- C19orf44 | c.236G>A p.C79Y | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV99522173; called by muse, mutect2, varscan2
- C19orf44 | c.1264G>A p.A422T | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV99685139; called by muse, mutect2, varscan2
- C1QTNF7 | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 25/70 reads (36%) | catalogued as COSV99765183; called by muse, mutect2, varscan2
- C1orf127 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as COSV100983480; called by muse, mutect2, varscan2
- C20orf194 | c.2969C>T p.A990V | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.124); catalogued as COSV99330711; called by muse, mutect2, varscan2
- C2orf73 | c.622dup p.T208Nfs*28 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | catalogued as rs772729186, COSV58310692; called by mutect2, varscan2
- C2orf78 | c.1224G>T p.E408D | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.811); catalogued as COSV101280962; called by muse, mutect2, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 24/66 reads (36%) | catalogued as rs201447915; called by mutect2, varscan2
- C5AR2 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as rs765679507, COSV99953747; called by muse, mutect2, varscan2
- C5orf15 | c.437G>A p.G146D | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.799); catalogued as rs1561574378, COSV99198321; called by muse, mutect2, varscan2
- C7orf26 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs750666334, COSV100732900; called by muse, mutect2, varscan2
- CABIN1 | c.3355T>C p.W1119R | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99573160; called by muse, mutect2, varscan2
- CACNA1B | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1194904886, COSV53139010; called by muse, mutect2, varscan2
- CACNA1D | c.5572C>A p.P1858T (on ENST00000350061 / NM_001128840.3; = p.P1878T on NM_000720.4) | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.019); catalogued as COSV99858033; called by muse, mutect2, varscan2
- CACNA1E | c.3299A>G p.K1100R | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100702451; called by muse, mutect2, varscan2
- CACNA1E | c.5849C>A p.A1950D | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV100702453; called by muse, mutect2, varscan2
- CACNA1G | c.2812T>C p.S938P | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.105); catalogued as COSV100661760; called by muse, mutect2, varscan2
- CACNA1I | c.854del p.P285Rfs*69 | Frame Shift Del (DEL) | VAF 21/51 reads (41%) | catalogued as COSV100359312; called by mutect2, pindel, varscan2
- CACNA1I | c.2331C>T p.S777= | Splice Region (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100360185; called by muse, mutect2, varscan2
- CACNA1I | c.3904T>C p.S1302P | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100360187; called by muse, mutect2, varscan2
- CAD | c.2755C>A p.L919I | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.9); catalogued as COSV99254989; called by muse, mutect2, varscan2
- CALM3 | c.35A>G p.E12G | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as COSV99355227; called by muse, mutect2, varscan2
- CALY | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.399); catalogued as COSV99428637; called by muse, mutect2, varscan2
- CAMSAP1 | c.1396del p.T466Pfs*46 | Frame Shift Del (DEL) | VAF 19/37 reads (51%) | catalogued as rs201838505; called by mutect2, varscan2
- CAND1 | c.1591C>T p.P531S | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.021); catalogued as COSV101607318; called by muse, mutect2, varscan2
- CAPN12 | c.1927T>A p.Y643N | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV99400158; called by muse, mutect2, varscan2
- CAPN5 | c.677T>C p.L226P (on ENST00000456580; = p.L186P on NM_004055.5) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99582087; called by muse, mutect2, varscan2
- CARD9 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1273655087, COSV100261170; called by muse, mutect2, varscan2
- CASK | c.2221A>G p.T741A (on ENST00000378163 / NM_001367721.1; = p.T736A on NM_003688.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100587155; called by muse, mutect2, varscan2
- CATSPER3 | c.574G>A p.A192T | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs145171708; called by muse, mutect2, varscan2
- CATSPERD | c.392-2A>G p.X131_splice | Splice Site (SNP) | VAF 9/111 reads (8%) | catalogued as COSV101062551; called by muse, mutect2
- CBFA2T3 | c.974A>G p.Q325R | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.013); catalogued as rs1349200952, COSV99241734; called by muse, mutect2, varscan2
- CC2D2B | c.454C>T p.L152F | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100729338, COSV100729414; called by muse, mutect2, varscan2
- CCDC106 | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100454243; called by muse, mutect2, varscan2
- CCDC110 | c.2030T>C p.L677P | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as COSV100293918; called by muse, mutect2, varscan2
- CCDC146 | c.2180T>C p.L727P | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99592566; called by muse, mutect2, varscan2
- CCDC151 | c.884A>C p.K295T | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100710519; called by muse, mutect2, varscan2
- CCDC27 | c.298A>G p.S100G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV99622432; called by muse, mutect2, varscan2
- CCDC30 | c.1690A>G p.N564D (on ENST00000340612; = p.N521D on NM_001080850.3) | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV100501307; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC62 | c.2036del p.N679Ifs*18 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs1053262354; called by mutect2, pindel, varscan2
- CCDC74B | c.201G>A p.M67I | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.055); catalogued as COSV100134440; called by muse, mutect2, varscan2
- CCDC81 | c.614G>A p.S205N (on ENST00000445632 / NM_001156474.2; = p.S115N on NM_021827.4) | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV99564306; called by muse, mutect2, varscan2
- CCDC88C | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.091); catalogued as rs1290345070, COSV101105601; called by mutect2, varscan2
- CCS | c.285dup p.P96Afs*16 | Frame Shift Ins (INS) | VAF 15/38 reads (39%) | catalogued as rs759691599; called by mutect2, varscan2
- CD276 | c.1241C>T p.A414V (on ENST00000318443 / NM_001024736.2; = p.A196V on NM_025240.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.975); catalogued as COSV100573353; called by muse, mutect2, varscan2
- CD48 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100924229; called by muse, mutect2, varscan2
- CDC20 | c.802T>C p.S268P | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs752281358, COSV100196463; called by muse, mutect2, varscan2
- CDC40 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.87); PolyPhen benign (0.043); catalogued as rs936387655, COSV100309295; called by muse, mutect2, varscan2
- CDC40 | c.401C>T p.T134I | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100309299; called by muse, mutect2, varscan2
- CDC7 | c.92del p.N31Tfs*51 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as rs762194001; called by mutect2, varscan2
- CDCP1 | c.1634G>A p.G545D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.408); catalogued as COSV99944037; called by muse, mutect2, varscan2
- CDH22 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as rs747134732, COSV100952845; called by muse, mutect2, varscan2
- CDH26 | c.395T>A p.V132D | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99722369; called by muse, mutect2
- CDH6 | c.873A>T p.K291N | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.805); catalogued as COSV99419078; called by muse, mutect2
- CDK19 | c.449G>T p.R150I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.35); catalogued as COSV100098483; called by muse, mutect2, varscan2
- CDK8 | c.896A>G p.K299R | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.327); catalogued as COSV101037209; called by muse, mutect2, varscan2
- CDYL2 | c.877G>A p.D293N | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980430837, COSV101629558; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 18/52 reads (35%) | catalogued as rs763090473; called by mutect2, varscan2
- CEBPZ | c.383C>T p.T128I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV99135548; called by muse, mutect2, varscan2
- CECR2 | c.1403C>T p.A468V (on ENST00000342247 / NM_001290047.2; = p.A285V on NM_001290046.1) | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.68); catalogued as COSV99377838; called by muse, mutect2, varscan2
- CECR2 | c.2822A>G p.H941R (on ENST00000342247 / NM_001290047.2; = p.H758R on NM_001290046.1) | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.092); catalogued as rs766008292, COSV99377842; called by muse, mutect2, varscan2
- CELSR1 | c.8953A>G p.R2985G | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.15); catalogued as COSV99418190; called by muse, mutect2, varscan2
- CELSR1 | c.2852G>A p.R951H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369542180, COSV53097274; called by muse, mutect2, varscan2
- CELSR3 | c.9853C>T p.P3285S | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.022); catalogued as COSV99373455; called by muse, mutect2, varscan2
- CELSR3 | c.6194A>G p.H2065R | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.429); catalogued as COSV99373459; called by muse, mutect2, varscan2
- CEP128 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs772978343, COSV99382670; called by muse, mutect2, varscan2
- CEP170 | c.1031A>G p.Q344R | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100317027; called by muse, mutect2, varscan2
- CES3 | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.318); catalogued as rs765780089, COSV100309912; called by muse, mutect2, varscan2
- CFAP20DC | c.2333-1G>T p.X778_splice (on ENST00000482387 / NM_001351530.2; = p.X527_splice on NM_198463.4 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 13/23 reads (57%) | catalogued as COSV99918657; called by muse, mutect2, varscan2
- CFAP47 | c.4923del p.G1642Efs*33 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as COSV57977498; called by mutect2, pindel, varscan2
- CFAP65 | c.5361G>T p.E1787D | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.217); catalogued as COSV100445096; called by muse, mutect2
- CFAP70 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs766866421, COSV60285375; called by muse, mutect2, varscan2
- CFC1 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as COSV99383472; called by muse, mutect2, varscan2
- CFHR3 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.733); catalogued as rs1368448906, COSV100807558; called by muse, mutect2, varscan2
- CH25H | c.290T>C p.M97T | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100897352; called by muse, mutect2, varscan2
- CHAF1B | c.1494-2A>G p.X498_splice | Splice Site (SNP) | VAF 5/10 reads (50%) | catalogued as COSV100023522; called by muse, mutect2, varscan2
- CHAMP1 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.086); catalogued as rs374239145; called by muse, mutect2, varscan2
- CHD5 | c.3267_3268insA p.G1090Rfs*38 | Frame Shift Ins (INS) | VAF 14/52 reads (27%) | catalogued as COSV99313510; called by pindel, varscan2
- CHPF2 | c.1609G>T p.G537* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV99223063; called by muse, mutect2, varscan2
- CHRDL1 | c.446G>A p.G149D (on ENST00000372045; = p.G155D on NM_145234.4) | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99488100; called by muse, mutect2, varscan2
- CHRM1 | c.212A>G p.D71G | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100186179; called by muse, mutect2, varscan2
- CILP | c.2182del p.T728Pfs*29 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | catalogued as COSV56028157; called by mutect2, pindel, varscan2
- CILP | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.968); catalogued as COSV99973349, COSV99973600; called by muse, mutect2, varscan2
- CIPC | c.272C>A p.P91H | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100694457; called by muse, mutect2, varscan2
- CIT | c.4714G>A p.A1572T | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.339); catalogued as COSV99949515; called by muse, mutect2, varscan2
- CKAP5 | c.2248G>A p.G750R | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV100370755; called by muse, mutect2, varscan2
- CLASP2 | c.466A>G p.N156D | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100223387; called by mutect2, varscan2
- CLASRP | c.296C>T p.T99I | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as COSV99673797; called by muse, mutect2, varscan2
- CLBA1 | c.212_213insA p.G72Wfs*11 | Frame Shift Ins (INS) | VAF 21/79 reads (27%) | catalogued as COSV101121030; called by mutect2, pindel, varscan2
- CLEC7A | c.62A>T p.D21V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.019); catalogued as COSV100021149; called by muse, mutect2, varscan2
- CLIC2 | c.458del p.P153Hfs*27 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | catalogued as COSV58936356; called by mutect2, pindel, varscan2
- CLIP2 | c.2714A>C p.K905T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV99791540; called by muse, mutect2, varscan2
- CLK2 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs144510106; called by muse, mutect2, varscan2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/30 reads (73%) | catalogued as rs369752219; called by mutect2, varscan2
- CLP1 | c.1271T>C p.L424P | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV100239799; called by muse, mutect2, varscan2
- CMC4 | c.58+2T>C p.X20_splice | Splice Site (SNP) | VAF 38/95 reads (40%) | catalogued as COSV100749891; called by muse, mutect2, varscan2
- CNPY3 | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100863606; called by muse, mutect2, varscan2
- COASY | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV99888420; called by muse, mutect2, varscan2
- COASY | c.1647G>T p.W549C | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99888422; called by muse, mutect2, varscan2
- COG7 | c.78G>T p.K26N | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs375531332; called by muse, mutect2, varscan2
- COIL | c.587del p.K196Rfs*13 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | catalogued as rs748995811; called by mutect2, varscan2
- COL10A1 | c.1210G>T p.G404W | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99684229; called by muse, mutect2, varscan2
- COL11A1 | c.5331A>T p.Q1777H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as COSV100616420; called by muse, mutect2, varscan2
- COL13A1 | c.1123G>A p.D375N (on ENST00000398978 / NM_001130103.2; = p.D318N on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as rs769993863, COSV62574675; called by muse, mutect2, varscan2
- COL21A1 | c.2807G>A p.C936Y | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99778612; called by muse, mutect2, varscan2
- COL4A1 | c.2405G>C p.G802A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1301668632, COSV101011142, COSV65426954; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL4A2 | c.4109A>G p.K1370R | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.898); catalogued as COSV100847338; called by muse, mutect2
- COL4A3 | c.2168C>A p.P723H | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101170217; called by muse, mutect2, varscan2
- COL4A5 | c.1780-2A>G p.X594_splice | Splice Site (SNP) | VAF 45/118 reads (38%) | catalogued as COSV100087624; called by muse, mutect2, varscan2
- COL5A1 | c.2365C>A p.P789T | Missense Mutation (SNP) | VAF 39/109 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100879889, COSV100880384; called by muse, varscan2
- COL5A1 | c.2385G>A p.K795= | Splice Region (SNP) | VAF 52/101 reads (51%) | catalogued as rs1554797638, COSV100879890; ClinVar: uncertain significance; called by muse, varscan2
- COL6A6 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV100650222; called by muse, mutect2, varscan2
- COL6A6 | c.1584dup p.A529Sfs*24 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | catalogued as rs780840044; called by mutect2, pindel, varscan2
- COLGALT1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as rs775756264, COSV99395037; called by muse, mutect2, varscan2
- COLGALT2 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100730616; called by muse, mutect2, varscan2
- COPG1 | c.935A>G p.N312S | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs767165798, COSV100135585; called by muse, mutect2
- CPA1 | c.147+2T>C p.X49_splice | Splice Site (SNP) | VAF 6/19 reads (32%) | catalogued as COSV50570227, COSV99163262; called by muse, mutect2, varscan2
- CPA4 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 53/119 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV55984709, COSV99744934; called by muse, mutect2, varscan2
- CPM | c.749A>T p.N250I | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV100615065; called by muse, mutect2, varscan2
- CPSF1 | c.3812-5C>T | Splice Region (SNP) | VAF 15/29 reads (52%) | catalogued as COSV100450399; called by muse, mutect2, varscan2
- CPSF3 | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99432806; called by muse, mutect2, varscan2
- CPZ | c.761G>A p.G254D (on ENST00000360986 / NM_001014447.3; = p.G243D on NM_003652.3) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100248956; called by mutect2, varscan2
- CREB3 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as rs748137034, COSV100147688; called by muse, mutect2, varscan2
- CREB3 | c.593T>C p.L198P | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV100147689; called by muse, mutect2, varscan2
- CREB3L2 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs767776429, COSV100381894; called by muse, mutect2, varscan2
- CREBBP | c.6610C>T p.Q2204* | Nonsense Mutation (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99269918; called by muse, mutect2, varscan2
- CRIM1 | c.1082G>T p.G361V | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99753307; called by muse, mutect2, varscan2
- CRK | c.721A>G p.R241G | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100315631; called by muse, mutect2, varscan2
- CRMP1 | c.1016C>A p.A339D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.28); PolyPhen benign (0.056); catalogued as COSV100271812; called by muse, mutect2, varscan2
- CRNN | c.871G>A p.A291T | Missense Mutation (SNP) | VAF 85/379 reads (22%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV99664118; called by muse, mutect2, varscan2
- CRYBA2 | c.162T>C p.V54= | Splice Region (SNP) | VAF 8/25 reads (32%) | catalogued as COSV99838086; called by muse, mutect2, varscan2
- CRYBB1 | c.647G>T p.W216L | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV99316008; called by muse, mutect2, varscan2
- CRYL1 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100004357; called by muse, mutect2, varscan2
- CSF1 | c.548T>C p.V183A | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100294507, COSV60036003; called by muse, mutect2, varscan2
- CSF3R | c.72G>T p.E24D | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.412); catalogued as COSV100117689; called by muse, mutect2
- CSMD2 | c.1448T>A p.V483D | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV99589601; called by muse, mutect2, varscan2
- CSPG4 | c.4180A>G p.S1394G | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs376232582; called by muse, mutect2, varscan2
- CST5 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.174); catalogued as rs1258769574, COSV100489620; called by muse, mutect2, varscan2
- CSTF2T | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs139518067; called by muse, mutect2, varscan2
- CSTF3 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100124008; called by muse, mutect2, varscan2
- CTCF | c.2098G>T p.E700* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV99865286; called by muse, mutect2, varscan2
- CTDP1 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV99310547; called by muse, mutect2, varscan2
- CTNNA2 | c.527T>C p.F176S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1258697237, COSV100783797; called by muse, mutect2, varscan2
- CTPS2 | c.814C>A p.L272M | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as COSV100826819; called by muse, mutect2, varscan2
- CTSA | c.398G>A p.G133D | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99509835; called by muse, mutect2, varscan2
- CTTNBP2 | c.2731A>G p.R911G | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV99353872; called by muse, mutect2, varscan2
- CTTNBP2NL | c.233A>T p.N78I | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99599972; called by muse, mutect2, varscan2
- CUBN | c.3334G>A p.G1112R | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100912631; called by muse, mutect2, varscan2
- CUL1 | c.1480C>T p.Q494* | Nonsense Mutation (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100296642; called by muse, mutect2, varscan2
- CUL9 | c.2600C>T p.A867V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758017460, COSV99335352; called by muse, mutect2, varscan2
- CUX1 | c.1286C>T p.P429L | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as COSV52900322; called by muse, mutect2, varscan2
- CYB5A | c.392T>C p.M131T | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100200436; called by muse, mutect2, varscan2
- CYLC1 | c.1657G>A p.G553R | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.143); catalogued as rs1353493847, COSV100254594; called by muse, mutect2, varscan2
- CYP11B1 | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99455070; called by muse, mutect2, varscan2
- CYP27A1 | c.677T>C p.I226T | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV99298493; called by muse, mutect2, varscan2
- CYP2E1 | c.748G>A p.V250M | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.599); catalogued as COSV99428968; called by muse, mutect2, varscan2
- CYP2S1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs928276085, COSV100027454, COSV59506650; called by muse, mutect2
- CYP4F8 | c.1555C>A p.L519M | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100358122; called by muse, mutect2, varscan2
- CYP4Z1 | c.1235A>G p.H412R | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100497657; called by muse, mutect2, varscan2
- CYTH3 | c.829G>T p.G277W (on ENST00000396741; = p.G276W on NM_004227.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100084393, COSV60362948; called by muse, mutect2, varscan2
- CYTH4 | c.622C>T p.P208S | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99957911; called by muse, mutect2, varscan2
- DAB1 | c.161C>T p.A54V | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); catalogued as COSV100139989; called by muse, mutect2, varscan2
- DAB2 | c.1447C>T p.P483S | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.111); catalogued as COSV100297994; called by muse, mutect2, varscan2
- DAGLA | c.1472C>T p.T491I | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.386); catalogued as COSV99944359, COSV99944554; called by muse, mutect2, varscan2
- DCAF13 | c.337C>T p.R113* | Nonsense Mutation (SNP) | VAF 29/66 reads (44%) | catalogued as rs761301834, COSV52574581; called by muse, mutect2, varscan2
- DCAF8 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100470429; called by muse, mutect2, varscan2
- DCBLD2 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as COSV99504859, COSV99505083; called by muse, mutect2, varscan2
- DCBLD2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779687763, COSV100472241; called by muse, mutect2
- DCC | c.707T>C p.L236P | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.275); catalogued as COSV100499887, COSV100501623; called by muse, mutect2, varscan2
- DCHS1 | c.4025C>T p.A1342V | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as COSV100202009; called by muse, mutect2, varscan2
- DCLK3 | c.871C>T p.R291* | Nonsense Mutation (SNP) | VAF 25/61 reads (41%) | catalogued as rs753035174, COSV69362951; called by muse, mutect2, varscan2
- DCST2 | c.2243C>A p.A748D | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as COSV99421166; called by muse, mutect2, varscan2
- DDX20 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100865926; called by muse, mutect2, varscan2
- DDX5 | c.1095G>A p.G365= | Splice Region (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99857936; called by muse, mutect2, varscan2
- DDX50 | c.1258G>T p.G420W | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101007240; called by muse, mutect2, varscan2
- DDX53 | c.609A>G p.I203M | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV100028913; called by muse, mutect2, varscan2
- DDX60 | c.5023A>G p.T1675A | Missense Mutation (SNP) | VAF 39/74 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV101190454; called by muse, mutect2, varscan2
- DEF8 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.017); catalogued as rs1454907660, COSV99240443; called by muse, mutect2, varscan2
- DEFA4 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV99857713; called by muse, mutect2, varscan2
- DEFA6 | c.287G>A p.R96K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.191); catalogued as COSV52406435; called by muse, mutect2, varscan2
- DEK | c.897A>G p.K299= | Splice Region (SNP) | VAF 76/243 reads (31%) | catalogued as COSV99788881; called by muse, mutect2, varscan2
- DENND4B | c.2086G>T p.E696* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV100768635; called by muse, mutect2, varscan2
- DGAT2L6 | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs760655417, COSV100283971; called by muse, mutect2, varscan2
- DGKD | c.2132G>A p.G711D (on ENST00000264057 / NM_152879.3; = p.G667D on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99896262; called by muse, mutect2, varscan2
- DGKD | c.3401C>T p.A1134V (on ENST00000264057 / NM_152879.3; = p.A1090V on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs756546928, COSV99896263; called by muse, mutect2, varscan2
- DGKK | c.3135G>A p.M1045I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV65707961; called by muse, mutect2, varscan2
- DGKZ | c.1103G>A p.R368H (on ENST00000454345 / NM_001105540.2; = p.R180H on NM_003646.4) | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.43); catalogued as rs1275686839, COSV100551375; called by muse, mutect2, varscan2
- DGKZ | c.2025+1del | Frame Shift Del (DEL) | VAF 29/101 reads (29%) | catalogued as COSV100551416; called by mutect2, pindel, varscan2
- DHX16 | c.2997+1G>T p.X999_splice | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99527932; called by muse, mutect2, varscan2
- DHX32 | c.982dup p.R328Kfs*14 | Frame Shift Ins (INS) | VAF 41/116 reads (35%) | catalogued as rs757784865; called by mutect2, pindel, varscan2
- DHX34 | c.2279dup p.G761Rfs*4 | Frame Shift Ins (INS) | VAF 23/52 reads (44%) | catalogued as rs763046010; called by mutect2, varscan2
- DHX8 | c.1223C>T p.A408V | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); catalogued as COSV52251848; called by muse, mutect2, varscan2
- DHX9 | c.1516A>G p.S506G | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100841391; called by muse, mutect2
- DICER1 | c.5678T>C p.V1893A | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as rs1555365989, COSV58616363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DIDO1 | c.3175G>T p.G1059* | Nonsense Mutation (SNP) | VAF 19/48 reads (40%) | catalogued as COSV99825780; called by muse, mutect2, varscan2
- DIPK1C | c.920T>C p.M307T | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100679860; called by muse, mutect2, varscan2
- DIS3 | c.91T>C p.C31R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1340233326, COSV100411465; called by muse, mutect2
- DISP1 | c.3251C>T p.A1084V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.74); catalogued as COSV99450917; called by muse, mutect2, varscan2
- DLG3 | c.534G>A p.G178= | Splice Region (SNP) | VAF 50/118 reads (42%) | catalogued as COSV99529494; called by muse, mutect2, varscan2
- DLGAP3 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs1256722625, COSV99332606; called by muse, mutect2, varscan2
- DLX1 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1040620446, COSV100543224; called by muse, mutect2, varscan2
- DLX5 | c.722C>A p.P241H | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.372); catalogued as COSV99756464; called by muse, mutect2, varscan2
- DMBT1 | c.754C>T p.R252* | Nonsense Mutation (SNP) | VAF 102/298 reads (34%) | catalogued as rs972429706, COSV100352893; called by muse, varscan2
- DMGDH | c.1328C>T p.A443V | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV99668948; called by muse, mutect2
- DNAH1 | c.10067A>G p.Q3356R | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV101325678; called by muse, mutect2, varscan2
- DNAH10 | c.1759A>G p.I587V (on ENST00000409039; = p.I526V on NM_207437.3) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV101292229; called by muse, mutect2
- DNAH10 | c.8870T>C p.L2957P (on ENST00000409039; = p.L2896P on NM_207437.3) | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV101292230; called by muse, mutect2, varscan2
- DNAH11 | c.6985T>C p.Y2329H | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.967); catalogued as COSV60939155; called by muse, mutect2, varscan2
- DNAH2 | c.9389T>C p.V3130A | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101209284; called by muse, mutect2, varscan2
- DNAH2 | c.12200G>A p.C4067Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as COSV101209285; called by muse, mutect2, varscan2
- DNAH3 | c.4312A>G p.T1438A | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99767248; called by muse, mutect2, varscan2
- DNAI1 | c.1934T>G p.I645S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV99646801; called by muse, mutect2, varscan2
- DNAJC1 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.061); catalogued as rs749879261, COSV100981295; called by muse, mutect2, varscan2
- DNAJC13 | c.1898T>C p.L633P | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53453990; called by muse, mutect2, varscan2
- DNASE1 | c.691T>C p.C231R | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767031004, COSV99892504; called by muse, mutect2, varscan2
- DNHD1 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as COSV99600048; called by muse, mutect2, varscan2
- DNM1 | c.1672-2A>G p.X558_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | catalogued as COSV100359894; called by muse, mutect2, varscan2
- DOCK1 | c.697G>A p.V233I | Missense Mutation (SNP) | VAF 43/111 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV99729379; called by muse, mutect2, varscan2
- DOCK10 | c.2003A>G p.Y668C | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99289355; called by muse, mutect2, varscan2
- DOCK2 | c.1056G>T p.P352= | Splice Region (SNP) | VAF 17/50 reads (34%) | catalogued as COSV99912171; called by muse, mutect2, varscan2
- DOCK3 | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.827); catalogued as COSV56500285, COSV99811678; called by muse, mutect2, varscan2
- DOCK3 | c.5555del p.P1852Qfs*45 | Frame Shift Del (DEL) | VAF 28/72 reads (39%) | catalogued as rs782552436; called by mutect2, pindel, varscan2
- DOCK4 | c.2994C>A p.N998K | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV101447858; called by muse, mutect2, varscan2
- DOCK8 | c.5249A>G p.E1750G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as COSV66621390; called by muse, mutect2, varscan2
- DOK1 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as rs757410769, COSV99284050; called by muse, mutect2, varscan2
- DOK6 | c.686C>T p.A229V | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV101234481; called by muse, mutect2, varscan2
- DOP1A | c.4139G>T p.R1380M | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99381809; called by muse, mutect2, varscan2
- DOP1A | c.4912G>T p.G1638C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99381815; called by muse, mutect2, varscan2
- DOP1B | c.3338C>T p.A1113V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV101215330; called by muse, mutect2, varscan2
- DPEP3 | c.565C>A p.L189M | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV99262689; called by muse, mutect2, varscan2
- DPF2 | c.527C>T p.T176I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.521); catalogued as COSV99361632; called by muse, mutect2, varscan2
- DPF3 | c.545del p.G182Afs*90 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs756090930, COSV63504210; called by mutect2, pindel, varscan2
- DPH7 | c.1127C>A p.P376H | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV53022240, COSV99483517; called by muse, mutect2, varscan2
- DPP6 | c.1790G>T p.R597M (on ENST00000377770 / NM_001364500.2; = p.R535M on NM_001936.5) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100125349; called by muse, mutect2, varscan2
- DPY19L2 | c.588+2T>C p.X196_splice | Splice Site (SNP) | VAF 25/81 reads (31%) | catalogued as COSV100116759; called by muse, mutect2, varscan2
- DPY19L3 | c.290A>G p.Y97C | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639185; called by muse, mutect2, varscan2
- DPY19L4 | c.1922T>C p.L641P | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101363263; called by muse, mutect2, varscan2
- DPYSL3 | c.656G>A p.G219D | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100575087; called by muse, mutect2, varscan2
- DRP2 | c.1167C>G p.Y389* | Nonsense Mutation (SNP) | VAF 24/64 reads (38%) | catalogued as COSV100871899; called by muse, mutect2, varscan2
- DST | c.21195G>T p.E7065D (on ENST00000361203 / NM_001374722.1; = p.E4762D on NM_015548.5) | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99755467; called by muse, mutect2, varscan2
- DST | c.2101C>T p.L701F (on ENST00000361203 / NM_001374722.1; = p.L375F on NM_001723.6) | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160296672, COSV99755469; called by muse, mutect2, varscan2
- DTX1 | c.1693A>G p.T565A | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV55654122, COSV99921685; called by muse, mutect2, varscan2
- DYNC1I1 | c.629A>G p.E210G | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV100268278; called by muse, mutect2, varscan2
- DZANK1 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.711); catalogued as COSV99362393; called by muse, mutect2, varscan2
- E2F1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 8/19 reads (42%) | catalogued as rs1223127537, COSV55774398; called by muse, mutect2, varscan2
- EBF3 | c.854G>A p.G285D (on ENST00000355311 / NM_001375392.1; = p.G276D on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100799189; called by muse, mutect2, varscan2
- EBNA1BP2 | c.659T>C p.L220P | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV99355939; called by muse, mutect2
- ECHDC3 | c.646C>T p.L216F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.238); catalogued as COSV101004542; called by muse, mutect2, varscan2
- EDA | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100140864; called by muse, mutect2, varscan2
- EEF1AKNMT | c.1678G>A p.A560T (on ENST00000361735 / NM_015935.5; = p.A474T on NM_014955.3) | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.971); catalogued as COSV100675852; called by muse, mutect2, varscan2
- EGR1 | c.1000del p.H334Tfs*198 | Frame Shift Del (DEL) | VAF 33/94 reads (35%) | catalogued as rs746692720; called by pindel, varscan2
- EGR3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.067); catalogued as COSV100416185; called by muse, mutect2, varscan2
- EHMT1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs1311830257, COSV100603786; called by muse, mutect2, varscan2
- EIF2AK4 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.73); catalogued as rs776089345, COSV99774626; called by muse, mutect2, varscan2
- ELF3 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.601); catalogued as COSV100668758; called by muse, varscan2
- ELK1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.968); catalogued as COSV99902071; called by muse, mutect2
- ELP1 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV101010408; called by muse, mutect2, varscan2
- EMC2 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV99624108; called by muse, mutect2, varscan2
- EMILIN1 | c.1386dup p.R463Afs*46 | Frame Shift Ins (INS) | VAF 15/32 reads (47%) | catalogued as rs753533275; called by mutect2, varscan2
- EMSY | c.3601A>G p.T1201A | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100595689; called by muse, mutect2, varscan2
- ENAM | c.2453A>G p.Q818R | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.73); catalogued as COSV101253087; called by muse, mutect2, varscan2
- ENPP4 | c.1213C>A p.P405T | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.321); catalogued as COSV100320310; called by muse, mutect2, varscan2
- EP400 | c.3572T>C p.M1191T | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as COSV100201176; called by muse, mutect2, varscan2
- EP400 | c.8097A>G p.Q2699= | Splice Region (SNP) | VAF 14/34 reads (41%) | catalogued as COSV100201178; called by muse, mutect2, varscan2
- EPB41L2 | c.2243G>A p.S748N | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.195); catalogued as COSV100440671; called by muse, mutect2, varscan2
- EPB41L2 | c.2102A>T p.D701V | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.556); catalogued as COSV100440672; called by muse, mutect2, varscan2
- EPB41L3 | c.2923G>T p.V975L | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.047); catalogued as COSV100549055; called by muse, mutect2, varscan2
- EPHB2 | c.923G>A p.G308D | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.792); catalogued as COSV101006959; called by muse, mutect2, varscan2
- ERBB3 | c.1481-1G>A p.X494_splice | Splice Site (SNP) | VAF 7/31 reads (23%) | catalogued as COSV99916797; called by muse, mutect2, varscan2
- ERBB3 | c.3976C>A p.P1326T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57264274, COSV99916799; called by muse, varscan2
- ERCC6L2 | c.745A>G p.T249A | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV99998583; called by muse, mutect2, varscan2
- ERO1A | c.1358G>A p.S453N | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101193620; called by muse, mutect2, varscan2
- ERO1A | c.435T>C p.S145= | Splice Region (SNP) | VAF 24/54 reads (44%) | catalogued as rs1566642367, COSV101193621; called by muse, mutect2, varscan2
- ESCO1 | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV99332243; called by muse, mutect2, varscan2
- ESPL1 | c.5993A>G p.Y1998C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99229277; called by muse, mutect2, varscan2
- ESYT1 | c.1971G>T p.Q657H | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99919967; called by muse, mutect2, varscan2
- ETFA | c.561G>A p.K187= | Splice Region (SNP) | VAF 11/22 reads (50%) | catalogued as COSV99144222; called by muse, mutect2, varscan2
- EVC | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.29); PolyPhen benign (0.013); catalogued as rs926749491, COSV53829037; called by muse, mutect2, varscan2
- EVC2 | c.2885G>A p.G962D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.045); catalogued as CD098975, COSV100185883; called by muse, mutect2, varscan2
- EXOC3L1 | c.298C>A p.L100M | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99333671; called by muse, mutect2, varscan2
- EXT2 | c.1907C>T p.A636V (on ENST00000343631; = p.A669V on NM_000401.3) | Missense Mutation (SNP) | VAF 32/66 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100640602; called by muse, mutect2, varscan2
- EXTL2 | c.431A>G p.N144S | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs771820484, COSV100921099; called by muse, mutect2, varscan2
- EYA3 | c.625C>A p.Q209K | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.275); catalogued as COSV100870242; called by muse, mutect2, varscan2
- F5 | c.6477G>T p.E2159D | Missense Mutation (SNP) | VAF 34/132 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100889089; called by muse, mutect2, varscan2
- F5 | c.3932A>G p.N1311S | Missense Mutation (SNP) | VAF 122/629 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763030033, COSV100889090; called by muse, mutect2, varscan2
- FAM135B | c.2690A>G p.H897R | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.011); catalogued as COSV99423594; called by muse, mutect2, varscan2
- FAM135B | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.451); catalogued as COSV99423601; called by muse, mutect2, varscan2
- FAM13A | c.2354C>T p.A785V | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs757298567, COSV99983581; called by muse, mutect2, varscan2
- FAM149A | c.2001del p.Q668Rfs*23 (on ENST00000356371 / NM_001367768.2; = p.Q377Rfs*23 on NM_015398.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 20/52 reads (38%) | catalogued as COSV99906798; called by mutect2, pindel, varscan2
- FAM160B1 | c.671T>C p.L224S | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100985423; called by muse, mutect2, varscan2
- FAM199X | c.197G>T p.R66M | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.642); catalogued as COSV101534164; called by muse, mutect2, varscan2
- FAM210A | c.704G>T p.R235M | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.819); catalogued as COSV59185086; called by muse, mutect2, varscan2
- FAM214A | c.1187T>A p.F396Y | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.672); catalogued as COSV99957943; called by muse, mutect2, varscan2
- FAM222A | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); catalogued as rs1421341585, COSV100734522; called by muse, mutect2, varscan2
- FAM47B | c.1417G>T p.G473* | Nonsense Mutation (SNP) | VAF 26/63 reads (41%) | catalogued as COSV100264309; called by muse, mutect2, varscan2
- FAM47C | c.1516C>T p.R506C | Missense Mutation (SNP) | VAF 81/184 reads (44%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.093); catalogued as rs370557345, COSV63728974, COSV63729626; called by muse, mutect2, varscan2
- FAM47C | c.2624C>T p.T875I | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.098); catalogued as COSV100792513; called by muse, mutect2, varscan2
- FANCC | c.143T>C p.M48T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as rs1353498563, COSV100002421; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FANCL | c.904-1G>T p.X302_splice | Splice Site (SNP) | VAF 8/30 reads (27%) | catalogued as COSV99287290; called by muse, mutect2, varscan2
- FARP1 | c.2738A>G p.H913R | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.495); catalogued as COSV100130593; called by muse, mutect2, varscan2
- FARP2 | c.1361A>G p.D454G | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99884562; called by muse, mutect2, varscan2
- FASTK | c.1015C>T p.P339S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.251); catalogued as COSV99879733; called by muse, mutect2, varscan2
- FAT3 | c.12917G>A p.G4306D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV99965761; called by muse, mutect2, varscan2
- FAT4 | c.6846G>A p.V2282= | Splice Region (SNP) | VAF 32/84 reads (38%) | catalogued as rs773018653, COSV100628538; called by muse, mutect2, varscan2
- FAT4 | c.8683C>A p.Q2895K | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV100628545; called by muse, mutect2, varscan2
- FBLIM1 | c.590T>C p.V197A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100181702; called by muse, mutect2, varscan2
- FBLN2 | c.1864A>G p.N622D | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99851851; called by muse, mutect2, varscan2
- FBN3 | c.1803dup p.L602Afs*64 | Frame Shift Ins (INS) | VAF 19/60 reads (32%) | catalogued as rs772353703; called by mutect2, varscan2
- FBXL17 | c.1844A>G p.Y615C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as rs771577003, COSV100671275; called by muse, varscan2
- FBXL7 | c.850G>A p.V284M | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.202); catalogued as COSV61648269; called by muse, mutect2, varscan2
- FBXL8 | c.421G>A p.D141N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.075); catalogued as COSV99263508; called by muse, mutect2, varscan2
- FBXO24 | c.1694G>T p.R565M (on ENST00000241071 / NM_033506.3; = p.R603M on NM_012172.5) | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.172); catalogued as COSV99575310; called by muse, mutect2, varscan2
- FBXO34 | c.1331G>A p.S444N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.52); PolyPhen benign (0.01); catalogued as rs772617019, COSV100571935; called by muse, mutect2, varscan2
- FBXO9 | c.301G>A p.A101T | Missense Mutation (SNP) | VAF 51/120 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99762429; called by muse, mutect2, varscan2
- FBXW12 | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as rs777522192, COSV56486134; called by muse, mutect2, varscan2
- FBXW5 | c.1429C>A p.L477M | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99812470; called by muse, mutect2
- FCGR2B | c.140C>T p.P47L | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV52680857; called by muse, mutect2, varscan2
- FCRL1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.077); catalogued as COSV100839778; called by muse, mutect2, varscan2
- FCRL1 | c.227T>C p.M76T | Missense Mutation (SNP) | VAF 22/118 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.12); catalogued as COSV63823844, COSV63825058; called by muse, mutect2, varscan2
- FCRL3 | c.2174T>C p.V725A | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as COSV100943181; called by muse, mutect2, varscan2
- FCRLB | c.14C>T p.T5I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs201556818, COSV100396179; called by muse, mutect2, varscan2
- FCSK | c.1580G>A p.R527H | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs569142534, COSV99850833; called by muse, mutect2, varscan2
- FER1L6 | c.2799del p.R934Gfs*56 | Frame Shift Del (DEL) | VAF 42/120 reads (35%) | catalogued as rs770147778; called by mutect2, pindel, varscan2
- FES | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100183040; called by muse, mutect2, varscan2
- FGD4 | c.1072C>T p.L358F | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99847044; called by muse, varscan2
- FGF16 | c.427T>C p.W143R | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.822); catalogued as COSV101466315; called by muse, mutect2, varscan2
- FKBP15 | c.3152C>A p.P1051H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.224); catalogued as COSV99438800; called by muse, mutect2, varscan2
- FLG | c.8821G>T p.G2941W | Missense Mutation (SNP) | VAF 56/210 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV100911545; called by muse, mutect2
- FLNA | c.6344T>A p.I2115N (on ENST00000369850 / NM_001110556.2; = p.I2107N on NM_001456.3) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); catalogued as COSV100774691; called by muse, mutect2, varscan2
- FLNC | c.7922G>T p.R2641L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.087); catalogued as COSV99972485; called by muse, mutect2, varscan2
- FMNL2 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV99979600; called by muse, mutect2, varscan2
- FNBP1L | c.1399A>G p.K467E (on ENST00000271234 / NM_001164473.2; = p.K409E on NM_017737.5) | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99554432; called by muse, mutect2, varscan2
- FNIP1 | c.1117-1G>T p.X373_splice | Splice Site (SNP) | VAF 15/28 reads (54%) | catalogued as COSV100330426; called by muse, mutect2, varscan2
- FOXA2 | c.374C>T p.A125V (on ENST00000377115 / NM_153675.3; = p.A131V on NM_021784.5) | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs775592057, COSV101008349; called by muse, mutect2, varscan2
- FOXG1 | c.1339G>C p.A447P | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.601); catalogued as COSV100486789; called by muse, mutect2, varscan2
- FOXN1 | c.890T>C p.I297T | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs140230257; called by muse, mutect2, varscan2
- FREM2 | c.4412G>A p.C1471Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs995327518, COSV99748629, COSV99749111; called by muse, mutect2, varscan2
- FRMD4B | c.1603A>C p.K535Q | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.197); catalogued as COSV101273437; called by muse, mutect2, varscan2
- FRMD4B | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.559); catalogued as rs1378183640, COSV101273438; called by muse, mutect2, varscan2
- FRY | c.2869A>G p.K957E | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.546); catalogued as COSV100969218; called by muse, mutect2, varscan2
- FRYL | c.4910A>G p.E1637G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99976827; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSCN3 | c.322C>T p.Q108* | Nonsense Mutation (SNP) | VAF 34/90 reads (38%) | catalogued as COSV99133736; called by muse, mutect2, varscan2
- FTH1 | c.446T>C p.L149S | Missense Mutation (SNP) | VAF 44/100 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99861287; called by muse, mutect2, varscan2
- FTSJ1 | c.452G>A p.G151D | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50026111; called by muse, mutect2, varscan2
- FURIN | c.107T>C p.V36A | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.224); catalogued as COSV99184674; called by muse, mutect2
- FUZ | c.949G>T p.G317W | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV100571136; called by muse, mutect2, varscan2
- FYN | c.1477A>G p.I493V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1241865669, COSV99991725; called by muse, mutect2, varscan2
- FZD1 | c.1025T>C p.L342P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99842542; called by muse, mutect2, varscan2
- FZD5 | c.1225G>A p.V409M | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.924); catalogued as COSV54944604; called by muse, mutect2, varscan2
- FZD6 | c.1442T>C p.L481P | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100708370; called by muse, mutect2, varscan2
- GABBR1 | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100589684; called by muse, mutect2, varscan2
- GABBR2 | c.1046T>C p.V349A | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.79); PolyPhen probably damaging (0.989); catalogued as COSV99409997; called by muse, mutect2, varscan2
- GABRD | c.847+2T>C p.X283_splice | Splice Site (SNP) | VAF 14/35 reads (40%) | catalogued as COSV101059538; called by muse, mutect2, varscan2
- GABRG1 | c.1295T>C p.I432T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.45); PolyPhen benign (0.334); catalogued as COSV99777950; called by muse, mutect2, varscan2
- GABRP | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 21/39 reads (54%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.964); catalogued as COSV99516747; called by muse, mutect2, varscan2
- GABRQ | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs1366440737, COSV100941235; called by muse, mutect2, varscan2
- GAD2 | c.840T>C p.H280= | Splice Region (SNP) | VAF 25/55 reads (45%) | catalogued as COSV99393212; called by muse, mutect2, varscan2
- GAL3ST1 | c.125C>T p.A42V | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs545072220, COSV100143058; called by muse, mutect2, varscan2
- GALC | c.1549T>C p.F517L | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99729657; called by muse, mutect2, varscan2
- GALNT16 | c.75G>A p.W25* | Nonsense Mutation (SNP) | VAF 26/69 reads (38%) | catalogued as COSV61886114; called by muse, mutect2, varscan2
- GALNTL6 | c.1369dup p.E457Gfs*33 | Frame Shift Ins (INS) | VAF 28/98 reads (29%) | catalogued as rs1177099840; called by mutect2, pindel, varscan2
- GAPVD1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.681); catalogued as COSV99783149; called by muse, mutect2, varscan2
- GATD1 | c.646T>G p.C216G | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV100168632; called by muse, mutect2, varscan2
- GBP5 | c.943C>A p.L315M | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.492); catalogued as COSV100600056; called by muse, mutect2, varscan2
- GCN1 | c.6663+2T>C p.X2221_splice | Splice Site (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100325131; called by muse, mutect2, varscan2
- GDE1 | c.677A>G p.H226R | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.759); catalogued as COSV100783183; called by muse, mutect2, varscan2
- GDPD3 | c.661A>C p.I221L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.86); PolyPhen benign (0.01); catalogued as COSV99531537; called by muse, mutect2, varscan2
- GDPD4 | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.031); catalogued as COSV100265263; called by muse, mutect2, varscan2
- GDPD5 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.261); catalogued as rs778484378, COSV100409284; called by muse, mutect2, varscan2
- GEN1 | c.2281A>G p.T761A | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV100437959; called by muse, mutect2, varscan2
- GGN | c.1574C>T p.T525M | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs757820791, COSV99287458; called by muse, mutect2, varscan2
- GIGYF1 | c.1449G>T p.Q483H | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99309307; called by muse, mutect2, varscan2
- GINS3 | c.86A>G p.H29R | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1322175170, COSV100139306; called by muse, mutect2, varscan2
- GIPC3 | c.685dup p.A229Gfs*10 | Frame Shift Ins (INS) | VAF 34/83 reads (41%) | catalogued as rs748150647; called by mutect2, varscan2
- GJA3 | c.13A>G p.S5G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV99576364; called by muse, mutect2, varscan2
- GJA8 | c.792G>T p.K264N | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV99569354; called by muse, mutect2, varscan2
- GK | c.268G>A p.V90I | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV100970645; called by muse, mutect2, varscan2
- GK5 | c.1489G>A p.V497M | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV101242199; called by muse, mutect2, varscan2
- GLDC | c.616G>A p.A206T | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100394080; called by muse, mutect2
- GLI3 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101230029, COSV67893319; called by muse, mutect2, varscan2
- GLIS3 | c.1199T>C p.L400P | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100173922; called by muse, mutect2, varscan2
- GLRA2 | c.202+1G>A p.X68_splice | Splice Site (SNP) | VAF 27/62 reads (44%) | catalogued as COSV99490930; called by muse, mutect2, varscan2
- GMIP | c.557C>T p.T186I | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as COSV99179245; called by muse, mutect2, varscan2
- GNB3 | c.69A>C p.K23N | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.12); PolyPhen benign (0.029); catalogued as COSV99301206; called by muse, mutect2, varscan2
- GNL1 | c.1066T>C p.Y356H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV100925414; called by muse, mutect2, varscan2
- GNPDA2 | c.256C>A p.H86N | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV99776903; called by muse, mutect2, varscan2
- GOLPH3L | c.596T>C p.L199P | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777279460, COSV99653762; called by muse, mutect2, varscan2
- GON4L | c.3092C>A p.P1031H | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99674216; called by muse, mutect2, varscan2
- GORAB | c.241del p.S81Lfs*75 | Frame Shift Del (DEL) | VAF 26/141 reads (18%) | catalogued as rs1422022340; called by mutect2, pindel, varscan2
- GPA33 | c.440G>A p.G147D | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.713); catalogued as rs148089044; called by muse, mutect2, varscan2
- GPAM | c.1905T>C p.P635= | Splice Region (SNP) | VAF 9/21 reads (43%) | catalogued as rs1400294898, COSV100788204; called by muse, mutect2, varscan2
- GPATCH2 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 18/164 reads (11%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV100861381; called by muse, mutect2, varscan2
- GPATCH8 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV100132637; called by muse, mutect2, varscan2
- GPR119 | c.98T>A p.I33N | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99358620; called by muse, mutect2, varscan2
- GPR142 | c.1201A>G p.M401V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1160481896, COSV100170815; called by muse, mutect2, varscan2
- GPR162 | c.1033A>G p.M345V (on ENST00000311268 / NM_019858.2; = p.M61V on NM_014449.2) | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV99163760; called by muse, mutect2, varscan2
- GPR22 | c.181A>G p.T61A | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.983); catalogued as COSV99772058; called by muse, mutect2, varscan2
- GPR31 | c.374T>C p.L125P | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.88); catalogued as rs1437946771, COSV100834133; called by muse, mutect2, varscan2
- GPR75 | c.1310C>A p.P437Q | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100766068; called by muse, mutect2, varscan2
- GPRIN2 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1245567724, COSV100966379; called by muse, mutect2, varscan2
- GREB1 | c.548C>A p.P183H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99302869; called by muse, mutect2, varscan2
- GRHPR | c.494-2A>G p.X165_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV58943443; called by muse, mutect2, varscan2
- GRIA4 | c.584G>T p.R195M | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.894); catalogued as COSV99231264; called by muse, mutect2, varscan2
- GRIN2C | c.2209G>A p.A737T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.907); catalogued as COSV99500950; called by muse, mutect2, varscan2
- GRIN3A | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100701484, COSV62457873; called by muse, mutect2, varscan2
- GRIP2 | c.2981T>C p.M994T (on ENST00000619221; = p.M897T on NM_001080423.4) | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV99817274; called by muse, mutect2, varscan2
- GRIPAP1 | c.223A>G p.N75D | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV100904273; called by muse, mutect2, varscan2
- GRK2 | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1175693753; called by muse, mutect2, varscan2
- GRM3 | c.2495A>G p.K832R | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.973); catalogued as COSV100862524; called by muse, mutect2, varscan2
- GSDME | c.522G>A p.M174I | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as COSV61651199; called by muse, mutect2, varscan2
- GTF2E1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.811); catalogued as COSV52205710, COSV99381929; called by muse, mutect2, varscan2
- GTF3C1 | c.5541dup p.E1848Rfs*22 | Frame Shift Ins (INS) | VAF 23/68 reads (34%) | catalogued as rs763161381; called by mutect2, varscan2
- GTF3C1 | c.4118A>G p.K1373R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV100649377; called by muse, mutect2, varscan2
- GTPBP2 | c.360G>A p.M120I | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as COSV100199947; called by muse, mutect2, varscan2
- GUCY2C | c.1252T>A p.S418T | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99663610; called by muse, mutect2, varscan2
- GYG1 | c.143+1G>A p.X48_splice | Splice Site (SNP) | VAF 8/20 reads (40%) | catalogued as COSV56050368; called by muse, mutect2, varscan2
- H2BC15 | c.188T>C p.M63T | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV100356971; called by muse, mutect2, varscan2
- H4C9 | c.26A>G p.K9R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.143); catalogued as COSV100574891; called by muse, mutect2, varscan2
- HCLS1 | c.845T>C p.V282A | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100100643; called by muse, mutect2, varscan2
- HDAC8 | c.154A>G p.K52E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV101002369; called by muse, mutect2, varscan2
- HEATR4 | c.1540A>G p.T514A | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100620359; called by muse, mutect2, varscan2
- HEATR5B | c.5453T>C p.L1818P | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99249226; called by muse, mutect2, varscan2
- HEATR5B | c.1439T>C p.L480P | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99249229; called by muse, mutect2, varscan2
- HECTD1 | c.6890A>G p.H2297R | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.954); catalogued as rs202003389, COSV101237372; called by muse, mutect2, varscan2
- HECW1 | c.3320A>G p.Q1107R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.104); catalogued as COSV101223465; called by muse, mutect2, varscan2
- HEG1 | c.2020C>T p.P674S | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as rs1380944624, COSV100230465; called by mutect2, varscan2
- HELT | c.221G>T p.R74M | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.716); catalogued as COSV100132895, COSV58819590; called by muse, mutect2, varscan2
- HEPACAM2 | c.229C>T p.P77S (on ENST00000394468 / NM_001039372.4; = p.P65S on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.294); catalogued as COSV100506543; called by muse, mutect2, varscan2
- HEPH | c.479G>A p.S160N (on ENST00000343002; = p.S214N on NM_138737.5) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.95); PolyPhen benign (0.044); catalogued as COSV100294804; called by muse, mutect2, varscan2
- HERC1 | c.4817C>T p.A1606V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.021); catalogued as COSV101496548; called by muse, mutect2, varscan2
- HEXA | c.1100G>A p.G367D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.021); catalogued as rs751790384, COSV99173729; called by muse, mutect2, varscan2
- HEXA | c.506A>G p.H169R | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99173731; called by muse, mutect2, varscan2
- HEYL | c.851dup p.G285Wfs*37 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | catalogued as rs942293039; called by mutect2, pindel, varscan2
- HHAT | c.1262C>T p.P421L | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs766841031, COSV99804049; called by muse, mutect2, varscan2
- HID1 | c.2210C>T p.P737L | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60915000; called by muse, mutect2, varscan2
- HID1 | c.1635T>C p.D545= | Splice Region (SNP) | VAF 9/30 reads (30%) | catalogued as rs1440819991, COSV100585991; called by muse, mutect2, varscan2
- HIF3A | c.911A>G p.Y304C (on ENST00000377670 / NM_152795.4; = p.Y235C on NM_022462.4) | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99355736; called by muse, mutect2, varscan2
- HIPK1 | c.85T>A p.S29T | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as COSV101060379; called by muse, mutect2, varscan2
- HIPK3 | c.1559T>C p.L520P | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100305725; called by muse, mutect2, varscan2
- HIRA | c.1790A>G p.N597S | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99600320; called by muse, mutect2, varscan2
- HIRA | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV54280197, COSV99600323; called by muse, mutect2, varscan2
- HIVEP1 | c.7041del p.M2348Cfs*18 | Frame Shift Del (DEL) | VAF 29/72 reads (40%) | catalogued as COSV65104518; called by mutect2, pindel, varscan2
- HIVEP2 | c.2932A>C p.S978R | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99173357; called by muse, mutect2, varscan2
- HIVEP2 | c.371G>A p.W124* | Nonsense Mutation (SNP) | VAF 28/62 reads (45%) | catalogued as COSV99173358; called by muse, mutect2, varscan2
- HLA-DPB1 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as rs1167784257, COSV101331014; called by muse, mutect2
- HLA-DQA1 | c.727C>A p.L243M | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.979); catalogued as COSV100568072; called by muse, mutect2
- HLCS | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV60794395; called by muse, mutect2, varscan2
- HMCN1 | c.4733C>T p.A1578V | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.862); catalogued as COSV99628864; called by muse, mutect2, varscan2
- HMCN1 | c.6481A>T p.I2161F | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99628866; called by muse, mutect2, varscan2
- HMCN1 | c.14744T>C p.V4915A | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as COSV99628870; called by muse, mutect2, varscan2
- HMCN1 | c.15866G>A p.C5289Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54886675, COSV99628871; called by muse, mutect2, varscan2
- HMGXB4 | c.33T>A p.D11E | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.068); catalogued as COSV99330084; called by muse, mutect2, varscan2
- HMMR | c.1043A>G p.Q348R | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV100700995; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.155T>C p.V52A (on ENST00000354667 / NM_031243.3; = p.V40A on NM_002137.4) | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV100522933; called by muse, mutect2, varscan2
- HNRNPH3 | c.114G>A p.G38= | Splice Region (SNP) | VAF 12/44 reads (27%) | catalogued as COSV99769705; called by muse, mutect2, varscan2
- HOXA9 | c.742A>G p.R248G | Missense Mutation (SNP) | VAF 44/98 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764475721, COSV100604397; called by muse, mutect2, varscan2
- HPS4 | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.382); catalogued as COSV100404320; called by muse, mutect2, varscan2
- HPS5 | c.368G>A p.G123D (on ENST00000349215 / NM_181507.2; = p.G9D on NM_007216.4) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs751981193, COSV100834422; called by muse, mutect2, varscan2
- HPSE2 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100985808, COSV65196317; called by muse, mutect2, varscan2
- HR | c.2695C>T p.Q899* | Nonsense Mutation (SNP) | VAF 9/32 reads (28%) | catalogued as COSV100455804; called by muse, mutect2, varscan2
- HS6ST2 | c.728G>A p.G243D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100897185; called by muse, mutect2, varscan2
- HSF2 | c.1337C>T p.T446I | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV100869679; called by muse, mutect2, varscan2
- HSPA1A | c.206A>T p.D69V | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV100989382; called by muse, varscan2
- HSPBP1 | c.812T>C p.M271T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); catalogued as rs983027720, COSV99729072; called by muse, varscan2
- HTRA3 | c.1016G>A p.R339Q | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199908504, COSV100246332; called by muse, mutect2, varscan2
- HTT | c.3146T>C p.V1049A | Missense Mutation (SNP) | VAF 26/59 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV100750724; called by muse, mutect2, varscan2
- HUNK | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs1014549869, COSV99528452; called by muse, mutect2, varscan2
- HUWE1 | c.2924T>C p.V975A | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99472152; called by muse, mutect2, varscan2
- IARS2 | c.641C>T p.T214I | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100228299; called by muse, mutect2, varscan2
- IBTK | c.2095A>G p.K699E | Missense Mutation (SNP) | VAF 29/67 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.185); catalogued as COSV100090675; called by muse, mutect2, varscan2
- ICAM1 | c.1142T>G p.L381R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.501); catalogued as COSV99320780; called by muse, mutect2
- ICAM3 | c.946G>T p.G316* | Nonsense Mutation (SNP) | VAF 5/12 reads (42%) | catalogued as COSV99349024; called by mutect2, varscan2
- ICAM5 | c.697C>A p.L233I | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99703320; called by muse, mutect2, varscan2
- IFI16 | c.807T>A p.S269R | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.219); catalogued as COSV55535105, COSV99857524; called by muse, varscan2
- IFI16 | c.821A>G p.N274S | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.277); catalogued as rs377046298; called by muse, varscan2
- IFI30 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99717393; called by muse, mutect2, varscan2
- IFI35 | c.100G>A p.G34R | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs777691679, COSV99887786; called by muse, mutect2, varscan2
- IFNA16 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs1343756790, COSV101207069; called by muse, mutect2, varscan2
- IFNAR2 | c.301A>G p.S101G | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV100577100; called by muse, mutect2, varscan2
- IGHV4-28 | c.11T>C p.L4P | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.331); catalogued as rs1555483520; called by muse, mutect2, varscan2
- IGLC2 | c.199G>A p.A67T | Missense Mutation (SNP) | VAF 20/153 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as rs745386032; called by muse, mutect2, varscan2
- IGLON5 | c.422C>A p.P141H | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as COSV54538620; called by muse, mutect2, varscan2
- IGSF1 | c.2533G>T p.G845W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100812071; called by muse, mutect2, varscan2
- IGSF10 | c.7790C>T p.T2597I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.529); catalogued as rs1002821931, COSV99179781; called by muse, mutect2, varscan2
- IGSF3 | c.2750G>T p.S917I (on ENST00000369486 / NM_001007237.3; = p.S937I on NM_001542.4) | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.432); catalogued as COSV100604616, COSV59597750; called by muse, mutect2
- IGSF9B | c.2246A>T p.N749I | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100317563; called by muse, mutect2, varscan2
- IL10RA | c.1031C>T p.A344V | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV99923039; called by muse, mutect2, varscan2
- IL18R1 | c.773A>G p.D258G | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.037); catalogued as COSV99295083; called by muse, mutect2, varscan2
- IL23R | c.1552T>C p.S518P | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs373245679; called by muse, mutect2, varscan2
- IL31RA | c.1468A>G p.I490V | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1480286188, COSV99763097; called by muse, mutect2, varscan2
- IL31RA | c.1541A>G p.E514G | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV99763100; called by muse, mutect2, varscan2
- IL4I1 | c.1499C>T p.A500V | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV99680618; called by muse, mutect2, varscan2
- IL6R | c.938C>T p.T313M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.536); catalogued as rs746005168, COSV100690815; called by muse, mutect2, varscan2
- ILF3 | c.1548+1G>A p.X516_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99139686; called by muse, mutect2, varscan2
- INHBA | c.1274G>A p.C425Y | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637629; called by muse, mutect2, varscan2
- INO80 | c.4099C>T p.H1367Y | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.196); catalogued as rs371610578; called by muse, mutect2, varscan2
- INO80 | c.2274G>T p.K758N | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100731807; called by muse, mutect2
- INPP5J | c.2585A>G p.D862G (on ENST00000331075 / NM_001284285.2; = p.D494G on NM_001002837.2) | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV99311628; called by muse, mutect2, varscan2
- INPPL1 | c.2002C>T p.R668W | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs148045527; called by muse, varscan2
- INPPL1 | c.2019G>A p.W673* | Nonsense Mutation (SNP) | VAF 8/32 reads (25%) | catalogued as COSV53355049; called by muse, varscan2
- INTS2 | c.247T>C p.S83P | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV99248017, COSV99248105, COSV99248724; called by muse, mutect2, varscan2
- INTS3 | c.393G>A p.M131I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.584); catalogued as rs774744292, COSV100015965; called by muse, mutect2, varscan2
- INTS5 | c.323C>A p.P108H | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.656); catalogued as COSV100399605; called by muse, mutect2, varscan2
- INVS | c.478A>G p.N160D | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs147251525; called by muse, mutect2, varscan2
- INVS | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs774863900, COSV99317495; called by muse, mutect2, varscan2
- IPO8 | c.1273T>G p.F425V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99805256; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.481C>T p.Q161* (on ENST00000485419 / NM_001197113.1; = p.Q85* on NM_014575.3) | Nonsense Mutation (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100540821; called by muse, mutect2, varscan2
- IQGAP1 | c.1250A>G p.Q417R | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV99184972; called by muse, mutect2, varscan2
- IQSEC1 | c.1748A>G p.K583R | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as COSV99831838; called by muse, mutect2
- IQSEC3 | c.2972-2A>G p.X991_splice (on ENST00000538872 / NM_001170738.2; = p.X688_splice on NM_015232.1) | Splice Site (SNP) | VAF 14/39 reads (36%) | catalogued as COSV100407145; called by muse, mutect2, varscan2
- IRF5 | c.261G>T p.K87N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99977673; called by muse, mutect2, varscan2
- IRS4 | c.1093C>T p.P365S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV64536736; called by muse, mutect2, varscan2
- ITGA3 | c.2297+1G>A p.X766_splice | Splice Site (SNP) | VAF 10/33 reads (30%) | catalogued as COSV99143614; called by muse, mutect2, varscan2
- ITGAD | c.1838+1G>A p.X613_splice | Splice Site (SNP) | VAF 18/60 reads (30%) | catalogued as COSV101210464; called by muse, mutect2, varscan2
- ITGAL | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 46/89 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs776362360, COSV63325129; called by muse, mutect2, varscan2
- ITIH5 | c.2767C>A p.L923M | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99904592; called by muse, mutect2, varscan2
- ITIH5 | c.2623C>T p.P875S | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.014); catalogued as COSV99904596; called by muse, mutect2, varscan2
- ITPK1 | c.934C>A p.L312I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50895665, COSV99968485; called by muse, mutect2, varscan2
- ITPRIPL1 | c.608T>C p.V203A (on ENST00000439118 / NM_001008949.3; = p.V211A on NM_178495.6) | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100742185; called by muse, mutect2, varscan2
- ITSN1 | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67157632; called by muse, mutect2, varscan2
- IVL | c.1528C>A p.L510I | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.752); catalogued as rs1477070144, COSV100908157; called by muse, mutect2, varscan2
- JCAD | c.4040G>A p.C1347Y | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs758401924, COSV100948337; called by muse, varscan2
- JCAD | c.1268A>G p.Y423C | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100948339; called by muse, mutect2, varscan2
- JMJD1C | c.5813A>T p.K1938I | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100550535; called by muse, mutect2, varscan2
- KANK4 | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.454); catalogued as COSV62987401, COSV62990078; called by muse, mutect2, varscan2
- KAT2B | c.1429G>A p.A477T | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0.04); catalogued as COSV99769245; called by muse, mutect2, varscan2
- KAT6A | c.5899C>T p.P1967S | Missense Mutation (SNP) | VAF 37/82 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.727); catalogued as COSV99705034; called by muse, mutect2, varscan2
- KATNIP | c.874A>G p.K292E | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99851009; called by muse, mutect2, varscan2
- KCNA4 | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100068918; called by muse, mutect2, varscan2
- KCNB2 | c.173G>T p.R58M | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV101578776; called by muse, mutect2, varscan2
- KCNH1 | c.1148T>C p.V383A (on ENST00000271751 / NM_172362.3; = p.V356A on NM_002238.4) | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV99659055; called by muse, mutect2, varscan2
- KCNH4 | c.2943dup p.Y982Lfs*6 | Frame Shift Ins (INS) | VAF 26/81 reads (32%) | catalogued as rs1486940663; called by mutect2, pindel, varscan2
- KCTD1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58683720; called by muse, mutect2, varscan2
- KDELR2 | c.496T>C p.W166R | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99330551; called by muse, mutect2, varscan2
- KDM4A | c.1187C>T p.T396I | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as COSV100969493; called by muse, mutect2, varscan2
- KDM5A | c.5052G>T p.E1684D | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.899); catalogued as COSV101238813; called by muse, mutect2, varscan2
- KIAA1109 | c.232G>A p.V78I | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.956); catalogued as COSV52688799, COSV99163056; called by muse, mutect2, varscan2
- KIAA1109 | c.11935A>C p.S3979R | Missense Mutation (SNP) | VAF 28/57 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99163063; called by muse, mutect2, varscan2
- KIAA1109 | c.13999T>C p.C4667R | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99163064; called by muse, mutect2, varscan2
- KIAA1549L | c.5023C>T p.P1675S (on ENST00000321505; = p.P1972S on NM_012194.3) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as COSV100381500; called by muse, mutect2, varscan2
- KIDINS220 | c.478G>A p.G160S | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as COSV99875646; called by muse, mutect2, varscan2
- KIF13A | c.1191A>T p.E397D | Missense Mutation (SNP) | VAF 22/73 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV99435864; called by muse, mutect2, varscan2
- KIF17 | c.2134G>A p.A712T | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs1201941334, COSV99928974; called by muse, mutect2, varscan2
- KIF20B | c.1758del p.K586Nfs*2 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as rs753332734; called by mutect2, varscan2
1,611 further variants in this file (1,056 protein-altering or splice-affecting, 499 silent, 56 other) are not listed here.
